Somatic mutation profile of tumor specimen HCM-BROD-0962-C16-06A (aliquot HCM-BROD-0962-C16-06A-01D-A87L-36) from HCMI case HCM-BROD-0962-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G3; Age at diagnosis: 62.3 years (22,747 days).
Specimen HCM-BROD-0962-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3603dc6c-f6a2-456d-9ba2-5179d56a54a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0962-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0962-C16-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/186b5cb4-dc9a-47c4-8f80-3c7d9a9f481a

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 4, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY6 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 45/504 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57171037; called by muse, mutect2
- CNTNAP5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 34/495 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.709); catalogued as rs201163242, COSV70513494; called by muse, mutect2
- CYP3A5 | c.98T>C p.F33S | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867453902, COSV56118800; called by muse, mutect2
- DCDC1 | c.2683T>A p.W895R (on ENST00000597505 / NM_001367979.1; = p.W2R on NM_020869.3) | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100338696; called by muse, mutect2
- FREM1 | c.5476G>A p.E1826K | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as COSV66521187; called by muse, mutect2, varscan2
- HNRNPDL | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 64/762 reads (8%) | catalogued as rs921825556; called by muse, mutect2
- PPP1R27 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772428754; called by muse, mutect2
- SACS | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 24/316 reads (8%) | catalogued as COSV66533286; called by muse, mutect2
- TGM7 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 58/586 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.138); catalogued as rs754202746; called by muse, mutect2
- ZNF134 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 38/586 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV68696421; called by muse, mutect2
- ADGRF4 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2
- CDRT15 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 38/629 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.294); called by muse, mutect2
- CENPT | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 29/426 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHD8 | c.5014C>A p.H1672N (on ENST00000646647 / NM_001170629.2; = p.H1393N on NM_020920.4) | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2
- GLIPR2 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 15/434 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- GPR179 | c.5162G>A p.G1721E (on ENST00000621958; = p.G1720E on NM_001004334.4) | Missense Mutation (SNP) | VAF 23/818 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.278); called by muse, mutect2
- ISM1 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 26/657 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA1109 | c.2321C>G p.S774* | Nonsense Mutation (SNP) | VAF 22/609 reads (4%) | called by muse, mutect2
- PIK3AP1 | c.1274T>G p.L425R | Missense Mutation (SNP) | VAF 40/632 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2
- PRPF31 | c.1400C>G p.A467G | Missense Mutation (SNP) | VAF 52/580 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SCN7A | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 46/574 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- SYNE1 | c.3580G>A p.V1194I (on ENST00000367255 / NM_182961.4; = p.V1201I on NM_033071.3) | Missense Mutation (SNP) | VAF 40/504 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- SYT1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.107); called by muse, mutect2
- TLK1 | c.456C>G p.Y152* | Nonsense Mutation (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- UGGT2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- ZNF101 | c.959G>T p.R320I | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.031); called by muse, mutect2
- ZNF536 | c.2074T>A p.S692T | Missense Mutation (SNP) | VAF 80/842 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ARMCX5 | c.1246T>C p.L416= | Silent (SNP) | VAF 10/316 reads (3%) | called by muse, mutect2
- CEP126 | c.2763G>A p.V921= | Silent (SNP) | VAF 42/560 reads (8%) | called by muse, mutect2
- CYP21A2 | c.303G>T p.V101= | Silent (SNP) | VAF 46/534 reads (9%) | called by muse, mutect2
- GALNT18 | c.1290T>A p.I430= | Silent (SNP) | VAF 36/336 reads (11%) | called by muse, mutect2
- IZUMO3 | c.423T>C p.G141= (on ENST00000543880 / NM_001365008.2; = p.G135= on NM_001271706.1) | Silent (SNP) | VAF 36/462 reads (8%) | called by muse, mutect2
- LAMA5 | c.7425C>T p.F2475= | Silent (SNP) | VAF 306/2585 reads (12%) | called by muse, mutect2, varscan2
- LILRA4 | c.1332G>A p.V444= | Silent (SNP) | VAF 45/630 reads (7%) | catalogued as COSV99393265; called by muse, mutect2
- NR5A2 | c.78G>T p.P26= | Silent (SNP) | VAF 28/454 reads (6%) | catalogued as COSV52656626; called by muse, mutect2
- MYC | c.-441T>G | 5'UTR (SNP) | VAF 58/620 reads (9%) | called by muse, mutect2
- PPHLN1 | c.1024+32C>T | Intron (SNP) | VAF 36/540 reads (7%) | called by muse, mutect2
